Gene-level copy-number profile of tumor specimen TCGA-08-0525-01A from TCGA case TCGA-08-0525, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.1 years (19,013 days).
Specimen TCGA-08-0525-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.3dee26ca-c7ed-49c4-8e83-e1ec978c12cf.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,183 have no estimate.
https://portal.gdc.cancer.gov/files/37fbe687-e0a6-486f-a5a8-8bb4bfd5f96f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 109; copy number 1: 8,797; copy number 2: 40,685; copy number 3: 5,849.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-08-0525-01): tumor purity 0.84, ploidy 1.88, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 109 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:36,496,128–38,701,517, 30 genes: LINC02505, AC125336.1, AC093746.1, LINC02616, AL136537.1, MIR4801, NWD2, C4orf19, AC022463.1, AC027607.1, RELL1, Y_RNA, AC108022.1, PGM2, AC021106.2, AC021106.1, TBC1D1, PTTG2, PSME2P4, MRPS33P2, AC098680.2, AC098680.1, LINC02513, AC024023.1, LINC01258, LINC01259, LINC02278, KLF3-AS1, AC021860.1, KLF3.
- chr9:21,802,636–30,575,012, 79 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8,797. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
